Somatic mutation profile of tumor specimen TCGA-AD-6901-01A (aliquot TCGA-AD-6901-01A-11D-1924-10) from TCGA case TCGA-AD-6901, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; Age at diagnosis: 78.2 years (28,579 days).
Specimen TCGA-AD-6901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e37894df-0715-4171-bb88-0b175dccee7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-6901-10A (Blood Derived Normal), aliquot TCGA-AD-6901-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61132188-579f-4baa-891f-9c9b2b3fae1f

The open-access MAF lists 282 somatic variants for this specimen: 209 protein-altering or splice-affecting, 69 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 69, Nonsense Mutation 10, Frame Shift Del 6, Splice Site 5, Splice Region 2, Frame Shift Ins 2, Intron 1, 3'Flank 1, 5'Flank 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 50/87 reads (57%) | hotspot (GDC flag); catalogued as CM992136, COSV57321785, COSV57346425; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 53/110 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC011462.1 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs139556493; called by muse, mutect2, varscan2
- ACIN1 | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.715); catalogued as COSV52983281; called by muse, mutect2, varscan2
- ACVR1C | c.642G>C p.W214C | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54650864; called by muse, mutect2, varscan2
- ADAM22 | c.1529G>C p.C510S | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55993149; called by muse, mutect2
- ADAMTS8 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759334242, COSV57298803; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs587652739, COSV55009166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP11 | c.5386C>G p.H1796D | Missense Mutation (SNP) | VAF 99/459 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV50305382; called by muse, mutect2, varscan2
- ALPG | c.578T>G p.V193G | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54968611; called by muse, mutect2, varscan2
- ALX3 | c.707del p.T236Mfs*95 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as COSV63929251; called by mutect2, pindel, varscan2
- ANK1 | c.4536T>C p.N1512= | Splice Region (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99223724; called by muse, mutect2, varscan2
- AP2A2 | c.2687C>T p.T896M | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.766); catalogued as rs748220772, COSV59965070; called by muse, mutect2
- APBA2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs145833994, COSV104435541; called by muse, mutect2, varscan2
- APCDD1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.509); catalogued as rs537794700, COSV100789890; called by muse, mutect2, varscan2
- ASAP1 | c.1555A>G p.M519V | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1211305056, COSV63055114; called by muse, mutect2, varscan2
- ASB11 | c.865C>A p.Q289K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV60354263, COSV60356221; called by muse, mutect2
- ASB3 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV55081096; called by muse, mutect2, varscan2
- ASXL1 | c.1835G>T p.R612M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60125303; called by muse, mutect2, varscan2
- AVPR2 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as COSV61687162; called by muse, mutect2, varscan2
- BCAR3 | c.2344T>A p.F782I | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53080287; called by muse, mutect2, varscan2
- BMP10 | c.703A>T p.S235C | Missense Mutation (SNP) | VAF 123/287 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as COSV54897666; called by muse, mutect2, varscan2
- CABP7 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs556835555, COSV53363127; called by muse, mutect2, varscan2
- CACNA1A | c.3740G>A p.R1247H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64214981; called by muse, mutect2, varscan2
- CACNA2D1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.182); catalogued as rs375189396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPRIN1 | c.1361C>G p.A454G | Missense Mutation (SNP) | VAF 161/236 reads (68%) | SIFT tolerated (0.57); PolyPhen benign (0.096); catalogued as rs762757969, COSV58222671; called by muse, mutect2, varscan2
- CCNF | c.1364C>A p.A455E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53544018; called by muse, mutect2, varscan2
- CCR8 | c.994A>G p.R332G | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100413000; called by muse, mutect2, varscan2
- CDH19 | c.857G>C p.G286A | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100050734, COSV50963327; called by muse, mutect2, varscan2
- CDKN2A | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs971657556, COSV58715027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDRT15 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs368683349, COSV69755328; called by muse, mutect2, varscan2
- CHRM3 | c.535A>G p.K179E | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55109192; called by muse, mutect2, varscan2
- CLRN2 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.866); catalogued as COSV72512637; called by muse, mutect2, varscan2
- COL9A1 | c.2290C>G p.Q764E | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.654); catalogued as COSV57895379; called by muse, mutect2, varscan2
- COPS2 | c.895-1G>C p.X299_splice | Splice Site (SNP) | VAF 50/115 reads (43%) | catalogued as COSV54648123; called by muse, mutect2, varscan2
- CRAMP1 | c.2278G>T p.A760S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV51967086, COSV51967134; called by muse, mutect2, varscan2
- CRYGC | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.882); catalogued as rs1223655646, COSV99965220; called by muse, mutect2, varscan2
- CRYZ | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.304); catalogued as COSV61718984; called by muse, mutect2, varscan2
- CX3CR1 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs200139865, COSV100843114; called by muse, mutect2, varscan2
- CYP2F1 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV58527966; called by muse, mutect2, varscan2
- CYP4F12 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs374928118; called by muse, mutect2, varscan2
- DCAF12L2 | c.1319A>G p.E440G | Missense Mutation (SNP) | VAF 76/100 reads (76%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV63584631; called by muse, mutect2, varscan2
- DCC | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 38/170 reads (22%) | catalogued as COSV100497852, COSV59080926, COSV59107578; called by muse, mutect2, varscan2
- DENND5A | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 116/183 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1236379978, COSV60238760; called by muse, mutect2, varscan2
- DMXL1 | c.6907C>T p.L2303F | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60723170; called by muse, mutect2, varscan2
- DNAAF3 | c.85+1G>T p.X29_splice (on ENST00000524407 / NM_001256715.2; = p.X76_splice on NM_178837.4) | Splice Site (SNP) | VAF 18/98 reads (18%) | catalogued as COSV100845843; called by muse, mutect2, varscan2
- DOCK10 | c.675T>A p.F225L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); catalogued as COSV51431237; called by muse, mutect2, varscan2
- DYRK4 | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV50547125; called by muse, mutect2, varscan2
- DYSF | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs144599077, CM1514313, COSV50316514; called by muse, mutect2, varscan2
- EFCAB12 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as rs1334979304, COSV58179391; called by muse, mutect2, varscan2
- ENOSF1 | c.1408A>G p.K470E (on ENST00000340116 / NM_001354066.2; = p.K436E on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs1305761428, COSV99200945; called by muse, mutect2, varscan2
- EPHB1 | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV67674070; called by muse, mutect2, varscan2
- EPOR | c.803T>G p.V268G | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as COSV55801817; called by muse, mutect2, varscan2
- FASN | c.1506G>T p.Q502H | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); catalogued as COSV60762605; called by muse, mutect2, varscan2
- FBN3 | c.7849C>T p.R2617W | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.967); catalogued as rs201196689, COSV54461815; called by muse, mutect2, varscan2
- FBP2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs766630515, COSV64694861; called by muse, mutect2
- FCGBP | c.7789G>A p.D2597N | Missense Mutation (SNP) | VAF 95/1138 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs756560346; called by muse, mutect2
- FCGBP | c.4186G>A p.D1396N | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs782628037, COSV99660624; called by muse, mutect2
- FN1 | c.4920C>A p.F1640L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV60566360; called by muse, mutect2, varscan2
- FNDC1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs766113964, COSV51950114; called by muse, mutect2, varscan2
- FOXL1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.131); catalogued as rs781452561, COSV57215520; called by muse, mutect2, varscan2
- FRAS1 | c.2362G>A p.G788S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53657936; called by muse, mutect2
- FSCN3 | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99133545; called by muse, mutect2, varscan2
- FSTL5 | c.2464G>C p.D822H | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60217455; called by muse, mutect2, varscan2
- GATA3 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1511800, COSV60517310; called by muse, mutect2, varscan2
- GOLGB1 | c.6051A>C p.K2017N | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100510258; called by muse, mutect2, varscan2
- GRIN2B | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.331); catalogued as COSV74208418; called by muse, mutect2, varscan2
- GRM1 | c.3187C>T p.R1063W | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV99263709; called by muse, mutect2, varscan2
- GTF2H1 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs377563352; called by muse, mutect2, varscan2
- GUCY1A2 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV56505791; called by muse, mutect2, varscan2
- HECTD4 | c.11989A>T p.R3997W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66401638; called by muse, mutect2, varscan2
- HECW1 | c.2501-1G>C p.X834_splice | Splice Site (SNP) | VAF 53/159 reads (33%) | catalogued as COSV67842171; called by muse, mutect2, varscan2
- HMGCR | c.2257G>T p.A753S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV55317007; called by muse, mutect2, varscan2
- HTR1B | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs931505695, COSV64051804; called by muse, mutect2, varscan2
- INHBA | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV54225929; called by muse, mutect2, varscan2
- ITGA6 | c.1390C>T p.L464F (on ENST00000442250; = p.L425F on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99904945; called by muse, mutect2, varscan2
- IVNS1ABP | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1324679768, COSV100832645, COSV62251242; called by muse, mutect2, varscan2
- KCNN3 | c.1697C>T p.A566V (on ENST00000618040 / NM_001204087.1; = p.A551V on NM_002249.6) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1557944131, COSV55216603; called by muse, mutect2
- KCNQ3 | c.411G>T p.L137F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66484455; called by muse, mutect2, varscan2
- KIAA1109 | c.5061A>T p.R1687S | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99145578; called by muse, mutect2
- KIR3DL1 | c.969G>T p.W323C | Missense Mutation (SNP) | VAF 402/593 reads (68%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.928); catalogued as COSV100428179; called by muse, mutect2, varscan2
- LAMA4 | c.3759C>A p.F1253L (on ENST00000230538 / NM_001105206.3; = p.F1246L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs1562643089, COSV57899078; called by muse, mutect2, varscan2
- LAMB1 | c.815T>C p.F272S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55971523; called by muse, mutect2, varscan2
- LIN28A | c.297G>C p.K99N | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV54263573; called by muse, mutect2, varscan2
- LPA | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.925); catalogued as COSV60314894; called by muse, mutect2, varscan2
- LRP3 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as COSV99472839; called by muse, mutect2, varscan2
- LRRC18 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV53286431; called by muse, mutect2, varscan2
- LSS | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV62703192; called by muse, mutect2, varscan2
- MAGEC1 | c.2416G>T p.A806S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.235); catalogued as COSV53568169, COSV53569400; called by muse, mutect2, varscan2
- MALT1 | c.1459G>A p.V487M | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61937032; called by muse, mutect2, varscan2
- MAP10 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.146); catalogued as COSV69362787; called by muse, mutect2, varscan2
- MAP1B | c.5902G>A p.E1968K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs999621263, COSV57095515, COSV99702129; called by muse, mutect2
- MB21D2 | c.1410C>G p.I470M | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101165000; called by muse, mutect2, varscan2
- MC4R | c.981C>G p.D327E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55353573; called by muse, mutect2, varscan2
- MEOX2 | c.524A>T p.Q175L | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV56295727; called by muse, mutect2, varscan2
- METTL7A | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs769150846, COSV59841242; called by muse, mutect2, varscan2
- MFAP5 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs765205871, COSV100848183, COSV63945013; called by muse, mutect2, varscan2
- MROH5 | c.3552G>A p.T1184= | Splice Region (SNP) | VAF 52/111 reads (47%) | catalogued as rs755445791, COSV100267033; called by muse, mutect2, varscan2
- MSN | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 94/144 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1455552920, COSV100814072; called by muse, varscan2
- MYH11 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362359781, COSV55545173; called by muse, mutect2, varscan2
- NALCN | c.3577C>T p.R1193C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1387780751, COSV51915760; called by muse, mutect2, varscan2
- NBEAL2 | c.3287T>C p.L1096P | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52763706; called by muse, mutect2, varscan2
- NEK10 | c.2237A>T p.Y746F | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV55366800; called by muse, mutect2, varscan2
- NEXMIF | c.2837A>G p.N946S | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV50181414; called by muse, mutect2, varscan2
- NOD2 | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs375713299, COSV100318034; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750613816, COSV58436399, COSV58451818; called by muse, mutect2, varscan2
- NYAP2 | c.1845C>A p.C615* | Nonsense Mutation (SNP) | VAF 25/124 reads (20%) | catalogued as COSV56019002; called by muse, mutect2, varscan2
- OR11A1 | c.120C>G p.I40M | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV65821449; called by muse, mutect2, varscan2
- OR5AR1 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs139968646; called by muse, mutect2, varscan2
- OR5D18 | c.340T>G p.F114V | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV61736553, COSV61739035; called by muse, mutect2
- OR5M8 | c.803A>T p.E268V | Missense Mutation (SNP) | VAF 388/425 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV59118553; called by muse, mutect2, varscan2
- OR8K5 | c.461T>A p.F154Y | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV57891724; called by muse, mutect2, varscan2
- OTULINL | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.564); catalogued as COSV57037044; called by muse, mutect2, varscan2
- PANX1 | c.684T>A p.C228* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV57135451; called by muse, mutect2, varscan2
- PCDHB1 | c.1143A>T p.K381N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV100128003; called by muse, mutect2, varscan2
- PCDHGB5 | c.2240C>A p.S747Y | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs372561902, COSV54031238; called by muse, mutect2, varscan2
- PCDHGB7 | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV54055400; called by muse, mutect2, varscan2
- PCSK2 | c.1789G>T p.A597S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV52745557; called by muse, mutect2, varscan2
- PDZRN4 | c.1486G>C p.E496Q (on ENST00000402685 / NM_001164595.2; = p.E238Q on NM_013377.4) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV100114984, COSV54220438, COSV99040486; called by muse, mutect2, varscan2
- PHLDB3 | c.1913A>G p.H638R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.385); catalogued as COSV99415094; called by muse, varscan2
- PIK3CG | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV63246379; called by muse, mutect2, varscan2
- PIK3R2 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1193898416, COSV55848777; called by muse, mutect2, varscan2
- PLCH1 | c.1477A>G p.K493E (on ENST00000340059 / NM_001130960.2; = p.K505E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs1221424324, COSV58212239; called by muse, mutect2, varscan2
- PLS1 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100537930; called by muse, mutect2, varscan2
- PRDM9 | c.2665G>A p.V889I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs773565590, COSV57007888, COSV99690542; called by muse, mutect2, varscan2
- PRICKLE1 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs768954477, CM119663, COSV58210964; called by muse, mutect2, varscan2
- PRICKLE1 | c.1771A>T p.S591C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58210967; called by muse, varscan2
- PRICKLE1 | c.1770G>T p.R590S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV58209915, COSV58210970; called by muse, varscan2
- PRICKLE1 | c.1769G>T p.R590M | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV58210972; called by muse, varscan2
- PSMA7 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 32/193 reads (17%) | catalogued as COSV99443697; called by muse, mutect2, varscan2
- PTBP2 | c.512T>G p.L171R (on ENST00000426398 / NM_001300986.2; = p.L163R on NM_021190.4) | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.056); catalogued as COSV64626892; called by muse, mutect2, varscan2
- PTPRZ1 | c.5132T>C p.L1711S | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66447652; called by muse, mutect2, varscan2
- RAD54L2 | c.2564A>C p.Q855P | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99620601; called by muse, mutect2, varscan2
- RADIL | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs201349013; called by muse, mutect2, varscan2
- RANBP9 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50580573, COSV50583017; called by muse, mutect2, varscan2
- RELN | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV58990404; called by muse, mutect2, varscan2
- RET | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.143); catalogued as rs1427186016, COSV60710609; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SCAF11 | c.4120G>T p.D1374Y | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65479629; called by muse, mutect2, varscan2
- SCAPER | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100240012, COSV57756976; called by muse, mutect2, varscan2
- SCN9A | c.2632T>C p.F878L (on ENST00000303354; = p.F867L on NM_002977.3) | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57628567; called by muse, mutect2, varscan2
- SDR9C7 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs374904822; called by muse, mutect2, varscan2
- SGCE | c.1265C>T p.T422M (on ENST00000647096; = p.T386M on NM_003919.3) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370800943; called by muse, mutect2, varscan2
- SGK1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as rs772324787, COSV52811055; called by muse, mutect2, varscan2
- SIGLEC14 | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 34/286 reads (12%) | catalogued as COSV99707031; called by muse, mutect2
- SIN3B | c.2651T>G p.F884C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56137190; called by muse, mutect2, varscan2
- SLC32A1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54147451; called by muse, mutect2, varscan2
- SLC43A3 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs375844954; called by muse, mutect2, varscan2
- SLC44A1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs368894258; called by muse, mutect2
- SLC5A4 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99831610, COSV99831864; called by muse, mutect2
- SLITRK3 | c.2435T>A p.L812Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV53854589; called by muse, mutect2, varscan2
- SLITRK4 | c.1342C>T p.L448F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62026655; called by muse, mutect2, varscan2
- SMARCA4 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV60811861; called by muse, mutect2, varscan2
- SOX2 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1334384230, COSV100327040; called by muse, mutect2
- SPTBN2 | c.6730C>A p.Q2244K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.602); catalogued as COSV59462967; called by muse, mutect2, varscan2
- SRMS | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs992148944, COSV53918892; called by muse, mutect2, varscan2
- STAB1 | c.5386C>T p.R1796W | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs201109781; called by muse, mutect2, varscan2
- TADA1 | c.999G>T p.L333F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.58); catalogued as COSV63310913; called by muse, mutect2
- TBC1D32 | c.156-1G>A p.X52_splice | Splice Site (SNP) | VAF 36/91 reads (40%) | catalogued as rs1165083020, COSV51556338; called by muse, mutect2, varscan2
- TCP11L1 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.595); catalogued as rs1426442304, COSV57515489; called by muse, mutect2, varscan2
- TGS1 | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52703806; called by muse, mutect2, varscan2
- THSD7A | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV70274689; called by muse, mutect2, varscan2
- TLL2 | c.2851A>G p.M951V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as rs1309081176, COSV63576988; called by muse, mutect2, varscan2
- TMEM174 | c.53T>A p.V18D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV57114539; called by muse, mutect2, varscan2
- TMEM63B | c.1895C>T p.T632M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1431296279, COSV52482364; called by muse, mutect2, varscan2
- TMEM87B | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200867510, COSV51719448; called by muse, mutect2, varscan2
- TNRC6B | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV57310330; called by muse, mutect2, varscan2
- TOP1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs56111014, COSV63696579; called by muse, mutect2, varscan2
- TPK1 | c.51G>C p.L17F | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.375); catalogued as rs775457916, COSV63650596; called by muse, mutect2, varscan2
- TPO | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV61097563, COSV61099702, COSV61113254; called by muse, mutect2, varscan2
- TRO | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV51509354, COSV99435635; called by muse, mutect2, varscan2
- TRRAP | c.8302C>T p.R2768W (on ENST00000359863 / NM_001244580.1; = p.R2750W on NM_003496.3) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs371221629; called by muse, mutect2, varscan2
- TSPYL5 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1409506792, COSV59070965; called by muse, mutect2, varscan2
- TTC8 | c.492T>A p.F164L (on ENST00000338104 / NM_001288781.1; = p.F174L on NM_144596.4) | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100581002; called by muse, mutect2, varscan2
- TTLL8 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367707905; called by mutect2, varscan2
- TTN | c.68629G>A p.D22877N (on ENST00000591111; = p.D15453N on NM_003319.4) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | PolyPhen probably damaging (0.996); catalogued as rs550593055, COSV59976547; called by muse, mutect2, varscan2
- TUBA3C | c.1334A>C p.E445A | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.292); catalogued as COSV101313829; called by muse, mutect2
- TXLNB | c.1421C>A p.S474Y | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV64445018, COSV64446028; called by muse, mutect2, varscan2
- UBE3A | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 34/161 reads (21%) | catalogued as COSV51671716; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3215dup p.V1073Sfs*2 | Frame Shift Ins (INS) | VAF 43/92 reads (47%) | catalogued as rs750418659; called by mutect2, varscan2
- UHRF1BP1L | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1188853611, COSV54443809; called by muse, mutect2, varscan2
- UPF1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99438697; called by muse, mutect2
- VPS13A | c.8438C>T p.A2813V | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV62441326; called by muse, mutect2, varscan2
- VPS16 | c.1358T>G p.L453R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100988244; called by muse, mutect2, varscan2
- WAC | c.1920A>C p.K640N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61570299; called by muse, mutect2, varscan2
- WDR11 | c.958T>C p.Y320H | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54794235; called by muse, mutect2, varscan2
- WDR81 | c.4231C>T p.R1411C (on ENST00000409644 / NM_001163809.2; = p.R360C on NM_152348.4) | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs939019178, COSV58481158; called by muse, mutect2, varscan2
- WDTC1 | c.2024G>T p.R675L (on ENST00000319394 / NM_001276252.2; = p.R674L on NM_015023.5) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV60090931; called by muse, mutect2, varscan2
- ZBBX | c.1757C>A p.P586H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV56804044; called by mutect2, varscan2
- ZBTB21 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750124231, COSV100176855; called by muse, mutect2, varscan2
- ZBTB41 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 26/122 reads (21%) | catalogued as COSV100962768, COSV66359016; called by muse, varscan2
- ZFP82 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as COSV67564978; called by muse, mutect2, varscan2
- ZNF492 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 64/435 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.113); catalogued as rs754422466, COSV71761810; called by muse, mutect2, varscan2
- ZNF571 | c.1166G>A p.R389K | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60735030; called by muse, mutect2, varscan2
- ZNF695 | c.1184T>G p.L395R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60587930; called by muse, mutect2
- ZNF761 | c.2034A>G p.I678M | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); catalogued as rs750594624, COSV61889688; called by muse, mutect2, varscan2
- ZNF831 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV64044601; called by muse, mutect2, varscan2
- ACACA | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ACVR2A | c.379del p.S127Qfs*23 | Frame Shift Del (DEL) | VAF 130/326 reads (40%) | called by mutect2, pindel, varscan2
- ATP9A | c.1926_1931dup p.M643_E644dup | In Frame Ins (INS) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- COMP | c.1669-11_1693del p.X557_splice | Splice Site (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- CPNE3 | c.327dup p.K110Efs*24 | Frame Shift Ins (INS) | VAF 25/127 reads (20%) | called by mutect2, pindel, varscan2
- DHX35 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- IVL | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.945); called by muse, varscan2
- LAMA5 | c.7084_7086del p.E2362del | In Frame Del (DEL) | VAF 14/93 reads (15%) | called by pindel, varscan2
- OR52N4 | c.169del p.L57Cfs*86 | Frame Shift Del (DEL) | VAF 287/590 reads (49%) | called by mutect2, pindel, varscan2
- PTPRO | c.2744_2747del p.N916Rfs*29 (on ENST00000281171 / NM_030667.3; = p.N888Rfs*29 on NM_002848.4) | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- SMOC2 | c.1253_1254del p.E418Gfs*17 (on ENST00000356284 / NM_001166412.2; = p.E429Gfs*17 on NM_022138.3) | Frame Shift Del (DEL) | VAF 22/152 reads (14%) | called by pindel, varscan2
- ACTL6B | c.135C>T p.A45= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV50516208; called by muse, mutect2, varscan2
- ADAMTS5 | c.1608G>A p.A536= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs149804004; called by muse, mutect2, varscan2
- ADAP2 | c.594G>T p.L198= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs1291117390, COSV58297260; called by muse, mutect2, varscan2
- AK3 | c.12C>T p.S4= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs1358615805, COSV63347389; called by muse, mutect2, varscan2
- ARHGEF28 | c.2208C>T p.S736= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as rs1346814189, COSV55266629; called by muse, mutect2, varscan2
- ARSA | c.669G>A p.L223= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1385065577, COSV53351602; called by muse, mutect2, varscan2
- ATG4B | c.915G>A p.P305= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs534411323, COSV60353484; called by muse, mutect2, varscan2
- BLVRB | c.342G>T p.L114= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1408035972, COSV54570725; called by muse, mutect2, varscan2
- CACNA1H | c.4710G>A p.A1570= | Silent (SNP) | VAF 45/75 reads (60%) | catalogued as rs759616283, COSV61987070; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA2D1 | c.2949C>T p.F983= (on ENST00000356253 / NM_001366867.1; = p.F971= on NM_000722.4) | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs761648569, COSV62371560, COSV62372187; called by muse, mutect2, varscan2
- CACNG4 | c.960G>T p.L320= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV50925231; called by mutect2, varscan2
- CARD9 | c.264G>A p.P88= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs753481864, COSV53738434; called by muse, mutect2, varscan2
- CCT8L2 | c.1533G>T p.V511= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as COSV63462842; called by muse, mutect2, varscan2
- CDH22 | c.1161C>T p.D387= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100952683; called by muse, mutect2
- CFAP70 | c.1341T>C p.G447= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100160124; called by muse, mutect2, varscan2
- CGNL1 | c.708C>T p.N236= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs772118237, COSV55569506; called by muse, mutect2
- CNTLN | c.915T>C p.A305= | Silent (SNP) | VAF 37/247 reads (15%) | catalogued as rs763256694, COSV52101626; called by muse, mutect2, varscan2
- COL7A1 | c.5928G>A p.R1976= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV60404635; called by muse, mutect2, varscan2
- CPNE8 | c.1470C>A p.S490= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV58854320; called by muse, mutect2, varscan2
- CXCR6 | c.96C>T p.V32= | Silent (SNP) | VAF 114/252 reads (45%) | catalogued as COSV56120820; called by muse, mutect2, varscan2
- DDX54 | c.870G>A p.R290= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV58376609; called by muse, mutect2, varscan2
- DLL4 | c.2049G>A p.T683= | Silent (SNP) | VAF 44/165 reads (27%) | catalogued as rs1292184163, COSV51075092; called by muse, mutect2, varscan2
- DMPK | c.216G>A p.E72= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52183513; called by muse, mutect2, varscan2
- E2F7 | c.945G>A p.L315= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as rs1265984503, COSV100523259; called by muse, mutect2
- EDNRB | c.1269C>G p.A423= (on ENST00000377211 / NM_001201397.1; = p.A333= on NM_000115.5) | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV57529015; called by muse, mutect2, varscan2
- EPHB3 | c.2016C>T p.T672= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs1560063907, COSV57808940; called by muse, mutect2, varscan2
- FAM71C | c.144C>T p.S48= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs151145389, COSV60944439; called by muse, mutect2, varscan2
- FMNL2 | c.858A>G p.A286= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99978787; called by muse, mutect2, varscan2
- GABBR1 | c.2034C>T p.Y678= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs758589287, COSV63541979; called by muse, mutect2, varscan2
- GAS6 | c.2031A>G p.A677= | Silent (SNP) | VAF 41/69 reads (59%) | catalogued as COSV59856818; called by muse, mutect2, varscan2
- GGT1 | c.1074C>A p.I358= | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as COSV50646581; called by muse, varscan2
- GGTLC2 | c.42C>A p.I14= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- GPR27 | c.1008C>T p.V336= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99816152; called by muse, mutect2
- HRNR | c.3306C>T p.H1102= | Silent (SNP) | VAF 40/196 reads (20%) | catalogued as rs576752881, COSV100912820; called by muse, mutect2, varscan2
- HS3ST2 | c.738C>T p.N246= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV54469753; called by muse, mutect2, varscan2
- INPP5J | c.2301C>A p.R767= (on ENST00000331075 / NM_001284285.2; = p.R399= on NM_001002837.2) | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV53213298; called by muse, mutect2, varscan2
- KCNH8 | c.2970C>T p.S990= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as COSV100108239; called by muse, mutect2, varscan2
- KIF4A | c.363G>T p.L121= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV65546496; called by muse, mutect2, varscan2
- KRT13 | c.564C>T p.D188= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs368494222; called by muse, mutect2, varscan2
- LPIN2 | c.54C>G p.L18= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV55245456; called by muse, mutect2, varscan2
- MAGI2 | c.186G>A p.S62= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV62633202, COSV62706246; called by muse, mutect2, varscan2
- MAPK6 | c.771G>A p.Q257= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99958826, COSV99959386; called by muse, varscan2
- NEXMIF | c.324C>T p.G108= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV50181864; called by muse, mutect2, varscan2
- NLRP6 | c.1671C>T p.R557= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV56462605; called by muse, mutect2, varscan2
- OPTC | c.42G>T p.L14= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV58115694, COSV58117873; called by muse, mutect2, varscan2
- OR14C36 | c.618C>T p.G206= | Silent (SNP) | VAF 52/206 reads (25%) | catalogued as rs767819229, COSV58602456; called by muse, mutect2, varscan2
- OR2Y1 | c.132C>T p.I44= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs201508793, COSV57138154; called by muse, mutect2, varscan2
- OR5T1 | c.423T>A p.P141= | Silent (SNP) | VAF 42/718 reads (6%) | catalogued as COSV57305294; called by muse, mutect2
- OSR2 | c.597G>A p.P199= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs768292533, COSV52555368, COSV52558960; called by muse, mutect2, varscan2
- PCDHA11 | c.2022G>A p.A674= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs1387416665, COSV56532362; called by muse, mutect2, varscan2
- PCDHA12 | c.1716C>T p.S572= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV56528377; called by muse, mutect2, varscan2
- PIK3R6 | c.696C>T p.A232= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100266040; called by muse, mutect2, varscan2
- PLG | c.471C>T p.N157= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs372617319; called by muse, mutect2, varscan2
- PPP2R3B | c.978G>T p.L326= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as COSV101065544, COSV66814631; called by muse, mutect2, varscan2
- PRSS57 | c.138C>T p.P46= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100249709, COSV61387007; called by muse, mutect2, varscan2
- RFX3 | c.1125G>C p.L375= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as COSV100174340, COSV100174472; called by muse, mutect2
- ROS1 | c.2403C>G p.L801= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV63862814; called by muse, mutect2, varscan2
- SCN7A | c.1911C>T p.F637= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as rs1467279581, COSV69275540; called by muse, mutect2, varscan2
- SH3D21 | c.1110C>T p.N370= (on ENST00000453908 / NM_001162530.2; = p.N259= on NM_024676.5) | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as rs774541805, COSV54634312; called by muse, mutect2, varscan2
- SLC25A17 | c.243C>T p.V81= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV54353530; called by muse, mutect2, varscan2
- SLC26A8 | c.1056C>T p.S352= | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as COSV62888114; called by muse, mutect2, varscan2
- SPTBN1 | c.1614C>G p.L538= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs761984098, COSV61690340; called by muse, mutect2, varscan2
- TMEM52B | c.318G>A p.S106= (on ENST00000381923 / NM_001079815.1; = p.S86= on NM_153022.4) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs746552314, COSV53730072; called by muse, mutect2, varscan2
- TNNT3 | c.480C>T p.S160= (on ENST00000397301 / NM_001367846.1; = p.S149= on NM_006757.4) | Silent (SNP) | VAF 48/75 reads (64%) | catalogued as COSV53490715; called by muse, mutect2, varscan2
- UBE3D | c.1071C>T p.T357= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs757867856, COSV99387946; called by muse, mutect2, varscan2
- UNC93A | c.318G>A p.P106= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs759198012, COSV57811403; called by muse, mutect2, varscan2
- UPRT | c.420G>A p.A140= | Silent (SNP) | VAF 114/181 reads (63%) | catalogued as rs772176065, COSV64912279; called by muse, mutect2, varscan2
- ZNF26 | c.9C>A p.T3= | Silent (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- ZNF597 | c.1182G>A p.A394= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as rs372972758, COSV100072109; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415344 T>C | 5'Flank (SNP) | VAF 11/44 reads (25%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2, varscan2
- MIR520H | n.21G>T | RNA (SNP) | VAF 66/135 reads (49%) | called by muse, mutect2, varscan2
- POM121 | chr7:72949005 G>A | 3'Flank (SNP) | VAF 24/110 reads (22%) | catalogued as rs782389344, COSV57525287; called by muse, mutect2, varscan2
- RMDN2 | c.452+21918del | Intron (DEL) | VAF 9/59 reads (15%) | catalogued as rs761706403; called by mutect2, varscan2
